Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7010, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7010-01A (Primary Tumor).

Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final I

Patient Name: MRN: Service Date/Time:
DOB/Age/Gender: Female Provider:
Location: Responsible Staff:

PATH. NO:
NAME: MED. REC. NO:
AGE/SEX: F DOB: SURGERY DATE:
RECEIVE DATE:
PATIENT PHONE NO.:
PHYSICIAN:
COPY TO:

PATHOLOGICAL DIAGNOSIS:
BRAIN BIOPSY, LEFT FRONTAL LOBE: ASTROCYTOMA, GEMISTOCYTIC.

Operation/Specimen: Left frontal lobe lesion FS.
Clinical History and Pre-Op Dx: Anaplastic astrocytoma with
radiation.

GROSS PATHOLOGY: Multiple 0.4-1.0 cm tissue fragments.
INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma in # 1-4.

MICROSCOPIC: Sections show neoplastic astrocytic infiltration with focal areas of hypercellular density. The predominant neoplastic cells are gemistocytic astrocytes with frequent nuclear hyperchromasia and pleomorphic. Mitotic figures are rare. There is mild endothelial proliferation. Necrotic foci are not seen. Focal aggregates of lymphocytic cells are seen within the tumor. Radiation necrosis is not present in the sections.

TISSUE COMMITTEE CODE: TC1.
BILLING CODES:

ICD-O-3
Astrocytoma, grade III
path
Astrocytoma, gemistocytic
Site: Brain, Supratentorial NOS
C71.0
Brain frontal lobe
C71.1
9/30/13

Source: NCI Genomic Data Commons file c95853a9-ad87-40db-8afb-bbe1c90543de (TCGA-DU-7010.B62E7173-FC3E-4D4C-B9C0-37110B1B58E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).